Gene-level copy-number profile of tumor specimen TCGA-QS-A8F1-01A from TCGA case TCGA-QS-A8F1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 85.9 years (31,386 days).
Specimen TCGA-QS-A8F1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.bcb7e25c-77aa-4599-be3e-2efbee5ef4e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QS-A8F1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f871571-cb03-4cb1-bc32-abe8488b6299

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,387; copy number 2: 15,361; copy number 3: 20,255; copy number 4: 16,856; copy number 5: 2,321; copy number 6: 1,423; copy number 7: 194; copy number 8: 331; copy number 9: 132; copy number 11: 85; copy number 12: 110; copy number 13: 42; copy number 15: 91; copy number 17: 36; copy number 18: 150; copy number 19: 10; copy number 24: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QS-A8F1-01A-21D-A37M-01): tumor purity 0.72, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,053 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:53,470,447–54,383,742, 17 genes, copy number 8: AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73.
- chr2:68,178,857–68,256,237, 1 gene, copy number 8 (within-gene range 3–8): PPP3R1.
- chr2:68,252,870–73,156,721, 102 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr2:82,476,825–83,219,105, 9 genes, copy number 9: AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1.
- chr3:167,239,843–170,305,977, 56 genes, copy number 11–17: ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA.
- chr4:78,551,747–78,939,438, 11 genes, copy number 7 (within-gene range 3–7): ANXA3, Y_RNA, LINC01094, HIGD1AP13, AC112253.1, AC098818.1, AC098818.2, BMP2K, AC098818.3, PAQR3, RN7SL127P.
- chr8:35,862,123–39,310,443, 85 genes, copy number 9–12 (broad region; genes not listed).
- chr8:48,913,916–51,321,118, 20 genes, copy number 9–19: AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1.
- chr8:57,289,552–58,272,450, 16 genes, copy number 8: RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2.
- chr10:84,003,332–87,435,035, 74 genes, copy number 8 (broad region; genes not listed).
- chr11:26,994,112–27,220,113, 3 genes, copy number 8: FIBIN, BBOX1, BBOX1-AS1.
- chr12:50,112,197–50,167,533, 2 genes, copy number 7 (within-gene range 3–7): AC074032.1, CERS5.
- chr12:50,185,580–50,191,363, 1 gene, copy number 7: AC008147.2.
- chr15:92,148,752–93,179,999, 32 genes, copy number 8: AC116903.2, AC116903.1, DUXAP6, NPM1P5, ST8SIA2, AC090985.1, ENO1P2, AC090985.2, C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5, FAM174B, AC091544.3, AC091544.7, AC091544.6, HMGN1P38, H2AZ2P1, AC091544.1, AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175, RGMA, YBX2P2, AC108457.1.
- chr15:93,257,198–93,301,647, 2 genes, copy number 8: AC112693.1, AC112693.2.
- chr19:23,762,944–24,163,425, 17 genes, copy number 8 (within-gene range 3–8): AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr19:38,184,376–40,898,282, 158 genes, copy number 7–9 (broad region; genes not listed).
- chr19:43,766,533–45,974,044, 126 genes, copy number 7–24 (within-gene range 2–24) (broad region; genes not listed).
- chr20:44,963,794–54,651,169, 243 genes, copy number 8–15 (broad region; genes not listed).
- chr20:56,358,974–56,602,113, 13 genes, copy number 9 (within-gene range 6–9): FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3.
- chr22:29,480,218–30,607,083, 53 genes, copy number 7: NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1, NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1, PES1, AC005006.1.
- chr22:49,166,421–49,664,968, 12 genes, copy number 9: Z82202.2, RPL35P8, Z82202.1, AC207130.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, Z97192.4.

Autosomal genes at a single copy (total copy number 1): 1,884. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
